Somatic mutation profile of tumor specimen ALCH-B3D7-TTP1-A (aliquot ALCH-B3D7-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B3D7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.4 years (27,159 days).
Specimen ALCH-B3D7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b1ea2f0-fb8e-4c44-b943-8a45127e3918.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3D7-NB1-A (Blood Derived Normal), aliquot ALCH-B3D7-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59210f3d-c02a-40e4-9690-d19082fc7084

The open-access MAF lists 539 somatic variants for this specimen: 376 protein-altering or splice-affecting, 97 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 327, Silent 97, Intron 32, Nonsense Mutation 16, RNA 16, Splice Site 14, Frame Shift Del 10, 3'UTR 8, 5'UTR 4, Splice Region 4, Frame Shift Ins 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDH | c.135A>T p.L45F | Missense Mutation (SNP) | VAF 80/365 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as rs1370743028; called by muse, mutect2, varscan2
- ABCA4 | c.5312+1G>T p.X1771_splice | Splice Site (SNP) | VAF 13/113 reads (12%) | catalogued as CS117280; called by muse, mutect2, varscan2
- ACE2 | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99383095; called by muse, mutect2, varscan2
- ACSM2A | c.1424C>A p.P475H (on ENST00000219054; = p.P396H on NM_001308169.2) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748455504; called by muse, mutect2, varscan2
- ADAMTS10 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs782586159; called by muse, mutect2, varscan2
- ADAMTS12 | c.2449C>A p.L817I | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as COSV100710462; called by muse, mutect2, varscan2
- AKT3 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as COSV55606920; called by muse, mutect2, varscan2
- BEST3 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 153/229 reads (67%) | catalogued as COSV58299517; called by muse, mutect2, varscan2
- BRIP1 | c.3284C>G p.S1095C | Missense Mutation (SNP) | VAF 65/397 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1479296707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BUD23 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs151200832; called by muse, mutect2, varscan2
- CACNA1E | c.6664G>T p.A2222S (on ENST00000367573 / NM_001205293.3; = p.A2179S on NM_000721.4) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs369634310; called by muse, mutect2, varscan2
- CATSPER1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.216); catalogued as rs745424701, COSV56411355; called by muse, mutect2, varscan2
- CDC14C | c.795G>C p.K265N (on ENST00000428251; = p.K158N on NM_152627.3) | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs539760248; called by muse, mutect2, varscan2
- CDCA7L | c.1215del p.C406Vfs*46 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as COSV100181107; called by mutect2, pindel, varscan2
- CDH10 | c.168G>C p.W56C | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100053134; called by muse, varscan2
- CDH19 | c.1459-1G>T p.X487_splice | Splice Site (SNP) | VAF 22/104 reads (21%) | catalogued as rs1248918843; called by mutect2, varscan2
- CFAP45 | c.279del p.T94Qfs*9 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | catalogued as rs1209352347; called by mutect2, pindel
- CFLAR | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as rs767106288; called by muse, mutect2, varscan2
- CFTR | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as rs1413926814; called by muse, mutect2, varscan2
- CNTNAP3 | c.3784A>G p.T1262A | Missense Mutation (SNP) | VAF 122/1742 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs772571729; called by muse, mutect2
- COL6A5 | c.7393C>T p.H2465Y (on ENST00000312481; = p.H2461Y on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55211902; called by muse, mutect2, varscan2
- CRB1 | c.917G>T p.W306L | Missense Mutation (SNP) | VAF 80/388 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.515); catalogued as COSV66345848; called by muse, mutect2, varscan2
- CSMD2 | c.8687del p.P2896Lfs*55 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as COSV99595959; called by mutect2, pindel, varscan2
- CSMD3 | c.944C>A p.P315Q | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52252359; called by muse, mutect2, varscan2
- DCDC1 | c.3779A>G p.N1260S (on ENST00000597505 / NM_001367979.1; = p.N367S on NM_020869.3) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1461827773; called by muse, mutect2
- DDX18 | c.1492G>C p.V498L | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as rs1382221562; called by muse, mutect2, varscan2
- DNAH7 | c.9926del p.G3309Afs*26 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | catalogued as COSV56763980; called by mutect2, pindel
- DOCK10 | c.4566C>A p.Y1522* | Nonsense Mutation (SNP) | VAF 6/146 reads (4%) | catalogued as COSV99289444; called by muse, mutect2
- DSEL | c.1852G>T p.D618Y | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1199278766, COSV59490233; called by muse, mutect2, varscan2
- DST | c.14960C>T p.P4987L (on ENST00000361203 / NM_001374722.1; = p.P2575L on NM_015548.5) | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV55019696; called by muse, mutect2, varscan2
- ELOVL2 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs755711524, COSV100676116; called by muse, mutect2, varscan2
- EPX | c.281A>T p.H94L | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as COSV56596172; called by muse, mutect2, varscan2
- ETNPPL | c.1083G>T p.R361S | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56594992; called by muse, mutect2, varscan2
- EVX1 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99764071; called by muse, mutect2, varscan2
- FLG | c.11281C>T p.H3761Y | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as rs1240524754; called by muse, mutect2
- FOLH1 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs367766463; called by muse, mutect2, varscan2
- FSIP2 | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs1195925708; called by muse, mutect2, varscan2
- FZD4 | c.1459G>T p.V487L | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs752990226; called by muse, mutect2, varscan2
- GFRA2 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100151632; called by muse, mutect2, varscan2
- GLB1L2 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs1405940548; called by muse, mutect2, varscan2
- GPRIN2 | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as rs912219056; called by muse, mutect2
- GRIK5 | c.1558G>C p.G520R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99490184, COSV99491022; called by muse, mutect2, varscan2
- GRIN2A | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58055684; called by muse, mutect2, varscan2
- GRM5 | c.2480C>A p.A827D | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV59610612; called by muse, mutect2
- GRM7 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.741); catalogued as COSV63170615; called by muse, mutect2, varscan2
- H1-2 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs775258009; called by muse, mutect2
- HCK | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 54/220 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs376025420; called by muse, mutect2, varscan2
- HSPB3 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 88/323 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148535965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL5RA | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1430267114; called by muse, mutect2
- ILF3 | c.1666G>T p.V556F | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51556389; called by muse, mutect2
- KCNA1 | c.919C>A p.R307S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM104754; called by muse, mutect2, varscan2
- KLHL42 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 136/249 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.409); catalogued as COSV67145829; called by muse, mutect2, varscan2
- KRTAP13-3 | c.241T>C p.Y81H | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV61878727; called by muse, mutect2
- LAMA5 | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs755943278; called by muse, varscan2
- LZTR1 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216720527, COSV104394421; called by muse, mutect2, varscan2
- MARCHF5 | c.551C>A p.P184Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1279422499; called by muse, mutect2, varscan2
- MC2R | c.808G>T p.V270F | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as COSV59620712; called by muse, mutect2, varscan2
- MILR1 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV74151739; called by muse, mutect2, varscan2
- MROH9 | c.931A>T p.M311L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs371280477; called by muse, mutect2, varscan2
- MUC17 | c.8519C>A p.P2840H | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV60295983; called by muse, mutect2, varscan2
- NAV2 | c.4868G>T p.R1623L (on ENST00000396087 / NM_001244963.2; = p.R1600L on NM_145117.5) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60656078; called by muse, mutect2, varscan2
- NCOA2 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1326252258; called by mutect2, varscan2
- NEO1 | c.3263G>T p.G1088V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs777905730; called by muse, mutect2, varscan2
- NFAT5 | c.2014C>G p.P672A | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1000716592; called by muse, mutect2, varscan2
- NLGN2 | c.1074C>G p.D358E | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as COSV100081214; called by muse, mutect2, varscan2
- NPAP1 | c.2315C>A p.P772H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61507886; called by muse, mutect2, varscan2
- NPAS1 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs536425599; called by muse, varscan2
- NPY2R | c.449G>T p.R150M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV61529116; called by mutect2, varscan2
- OPN3 | c.803G>T p.W268L | Missense Mutation (SNP) | VAF 124/517 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59366078; called by muse, mutect2, varscan2
- OR2L5 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.377); catalogued as COSV62365231; called by mutect2, varscan2
- OR2T3 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV62083081; called by muse, mutect2
- OR2T34 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 44/332 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV60901925; called by muse, mutect2, varscan2
- OR4E2 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as COSV57731695; called by muse, mutect2, varscan2
- OR4K5 | c.45G>T p.L15F | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as COSV100262438; called by muse, mutect2
- OR5D16 | c.457T>A p.W153R | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs950218176; called by muse, mutect2, varscan2
- PALB2 | c.3433G>T p.G1145C | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180177137, COSV99848018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH15 | c.4301C>T p.A1434V | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.085); catalogued as rs572629527, COSV57265897; called by muse, varscan2
- PCDH15 | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.961); catalogued as COSV100213918, COSV100214304; called by muse, mutect2, varscan2
- PCDH18 | c.3163G>T p.A1055S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs763502156, COSV100787236; called by muse, mutect2, varscan2
- PCDHB12 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.168); catalogued as rs782195330; called by muse, mutect2
- PDHA1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 37/73 reads (51%) | catalogued as COSV58834597; called by muse, mutect2, varscan2
- PECR | c.588C>G p.I196M | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54733393; called by muse, mutect2
- PEF1 | c.555G>C p.Q185H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs1277153576; called by muse, mutect2
- PEG3 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV55629844; called by muse, mutect2, varscan2
- PLCH1 | c.3139G>C p.A1047P (on ENST00000340059 / NM_001130960.2; = p.A1039P on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV58195069; called by muse, mutect2
- PLEK2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV53605158; called by muse, mutect2, varscan2
- PLET1 | c.254C>A p.A85E | Missense Mutation (SNP) | VAF 65/410 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1362974142; called by muse, mutect2, varscan2
- PPP3CA | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs762386324, COSV100547641; called by muse, mutect2, varscan2
- PRCC | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.153); catalogued as rs769733198, COSV54857853; called by muse, mutect2, varscan2
- PRUNE2 | c.5503C>A p.Q1835K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.122); catalogued as COSV100944516; called by muse, mutect2, varscan2
- PSG1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1058661; called by muse, mutect2, varscan2
- PTGER3 | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1255599929; called by muse, varscan2
- PTPRO | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99840573; called by muse, mutect2, varscan2
- RBBP7 | c.1172C>G p.S391* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100417936, COSV58113346; called by muse, mutect2
- REM1 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.901); catalogued as rs369078506; called by muse, mutect2, varscan2
- RGS3 | c.911G>T p.R304M (on ENST00000350696 / NM_001282923.2; = p.R192M on NM_017790.4) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58285357; called by muse, mutect2, varscan2
- RGSL1 | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as COSV54257814; called by muse, mutect2, varscan2
- RIT2 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56296943; called by muse, mutect2, varscan2
- RYR2 | c.12663C>A p.S4221R | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as rs370297602, COSV63693350; called by muse, mutect2, varscan2
- S1PR1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs756873576, COSV59513305; called by muse, mutect2, varscan2
- SETBP1 | c.2615G>T p.G872V | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99955576; called by muse, mutect2, varscan2
- SETD9 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99605610; called by muse, mutect2, varscan2
- SLC24A2 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV53862562, COSV99647442; called by muse, mutect2, varscan2
- SLC47A2 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV57629677; called by muse, varscan2
- SLC5A11 | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV61743564; called by muse, mutect2
- SLC5A12 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV68448104; called by muse, mutect2, varscan2
- SLC5A7 | c.1178C>A p.T393K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV50891479; called by muse, mutect2, varscan2
- SLC6A7 | c.1347G>T p.W449C | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as rs1244588370; called by muse, mutect2
- SLFN5 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs755184137, COSV55479960; called by muse, mutect2, varscan2
- SLITRK6 | c.775A>T p.S259C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV68389228; called by muse, mutect2, varscan2
- SMARCA4 | c.2050G>T p.V684L | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV60789381; called by muse, mutect2, varscan2
- SNTG1 | c.1057C>G p.R353G | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as rs764655031; called by muse, mutect2, varscan2
- SPNS1 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as COSV57954340; called by mutect2, varscan2
- SRGAP1 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61896902; called by muse, mutect2
- ST3GAL1 | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | PolyPhen benign (0.049); catalogued as COSV60615428; called by mutect2, varscan2
- SULF1 | c.1015C>A p.R339S | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52673496, COSV52687237; called by muse, mutect2, varscan2
- TET1 | c.6319C>T p.H2107Y | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV65385196; called by muse, mutect2
- TLCD1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs1477643971; called by muse, mutect2, varscan2
- TRIM42 | c.1216C>G p.Q406E | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV53880975, COSV99648392; called by muse, mutect2, varscan2
- TSPAN5 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99995157; called by muse, mutect2, varscan2
- TTC39B | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs779799745, COSV52612349; called by muse, mutect2, varscan2
- USH2A | c.5473G>A p.E1825K | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.138); catalogued as CM080612; called by muse, mutect2, varscan2
- VEPH1 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs772849491, COSV62882764; called by muse, mutect2, varscan2
- ZFHX3 | c.10295C>T p.S3432F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); catalogued as rs771247982, COSV51741487; called by muse, mutect2, varscan2
- ZNF280A | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV57482588; called by muse, mutect2
- ZNF778 | c.1025G>T p.C342F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100124311; called by muse, mutect2, varscan2
- ZNF831 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs771287739; called by mutect2, varscan2
- ZP4 | c.1078C>A p.L360M | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63910821; called by muse, mutect2, varscan2
- ABCA13 | c.2841C>A p.H947Q | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACACA | c.6455G>T p.G2152V | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACAD10 | c.783G>C p.K261N | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); called by muse, mutect2
- ADAM12 | c.1644C>G p.C548W | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM19 | c.1355dup p.A454Gfs*13 | Frame Shift Ins (INS) | VAF 32/121 reads (26%) | called by mutect2, pindel, varscan2
- ADAMTS14 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ADAMTS3 | c.2981G>T p.R994M | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ADCY10 | c.3078-1G>A p.X1026_splice | Splice Site (SNP) | VAF 28/128 reads (22%) | called by mutect2, varscan2
- ADGRB3 | c.3374C>A p.S1125Y | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ADGRG4 | c.6760G>T p.V2254F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- AIPL1 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- AKAP1 | c.2500+1G>T p.X834_splice | Splice Site (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- AMPH | c.897A>T p.K299N | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANGPT1 | c.1264G>T p.G422C | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD30B | c.2705C>A p.T902K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- APOB | c.7398A>T p.L2466F | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- APOB | c.5797T>A p.L1933M | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ARHGEF10L | c.1387C>G p.P463A | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ARPP21 | c.2401G>C p.A801P | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- ATP1A3 | c.2363C>A p.P788Q (on ENST00000545399 / NM_001256214.2; = p.P775Q on NM_152296.5) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BAALC | c.458C>A p.P153H (on ENST00000297574 / NM_001364874.1; = p.P118H on NM_024812.3) | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- BANK1 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- BCL11A | c.1205T>A p.V402D (on ENST00000335712 / NM_001365609.1; = p.V436D on NM_018014.4) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- C1QA | c.2dup p.M1? | Frame Shift Ins (INS) | VAF 17/75 reads (23%) | called by mutect2, pindel, varscan2
- C1QTNF2 | c.632C>T p.P211L (on ENST00000393975; = p.P166L on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf198 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
- CARD6 | c.1641G>A p.M547I | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CC2D2B | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC146 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- CCDC172 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- CCDC175 | c.1972C>A p.L658M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- CCDC178 | c.1366C>A p.L456I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CD177 | c.99G>T p.W33C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CD1D | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- CD2AP | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 87/395 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH20 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CDH8 | c.827T>A p.F276Y | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CECR2 | c.986A>G p.Q329R (on ENST00000342247 / NM_001290047.2; = p.Q166R on NM_001290046.1) | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CEP250 | c.3143A>G p.K1048R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CEP295 | c.1671+5G>T | Splice Region (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- CFAP46 | c.8078C>T p.P2693L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CFAP47 | c.7159G>A p.G2387S | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHAF1B | c.1308G>T p.Q436H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.125); called by mutect2, varscan2
- CHD8 | c.4267G>T p.E1423* (on ENST00000646647 / NM_001170629.2; = p.E1144* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- CHRM2 | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 79/467 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CIB4 | c.164T>G p.V55G | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CLCNKB | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- COL21A1 | c.2618G>T p.G873V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COMMD8 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 28/332 reads (8%) | called by muse, mutect2
- COPG1 | c.1419_1444del p.R474Gfs*3 | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel
- CTNND2 | c.1415C>A p.T472K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, varscan2
- CUBN | c.3434G>C p.S1145T | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.077); called by muse, mutect2
- CYP3A7 | c.489_511del p.E163Dfs*16 | Frame Shift Del (DEL) | VAF 36/286 reads (13%) | called by mutect2, varscan2
- DCHS1 | c.4046C>A p.S1349Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCHS2 | c.1679G>T p.W560L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- DCLK1 | c.1689-1G>T p.X563_splice | Splice Site (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- DCUN1D3 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DEFB124 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.431); called by muse, varscan2
- DENND4B | c.3025G>T p.G1009W | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); called by muse, varscan2
- DENND4B | c.1980G>T p.Q660H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKB | c.1662C>A p.S554R | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- DHX8 | c.1125del p.V376Sfs*6 | Frame Shift Del (DEL) | VAF 28/177 reads (16%) | called by mutect2, pindel, varscan2
- DIDO1 | c.5713G>T p.G1905C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.11818C>A p.L3940I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DSG1 | c.61G>A p.V21I | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EOMES | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); called by muse, varscan2
- ERN1 | c.2164A>T p.R722* | Nonsense Mutation (SNP) | VAF 28/129 reads (22%) | called by muse, mutect2, varscan2
- EVX1 | c.119A>T p.E40V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- FAM13A | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- FAM25A | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.059); called by muse, mutect2
- FAM47C | c.1129C>A p.H377N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FAM71B | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- FBN2 | c.8487C>A p.N2829K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FER1L6 | c.5235C>A p.F1745L | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FGD4 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- FILIP1L | c.2380C>G p.Q794E (on ENST00000354552 / NM_182909.3; = p.Q554E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.062); called by muse, mutect2
- FLG | c.11662C>A p.H3888N | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FLG2 | c.856A>T p.S286C | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, mutect2
- FLNC | c.7507G>T p.G2503W | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FOXF1 | c.978A>T p.Q326H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- FOXG1 | c.1056C>A p.N352K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FOXL2 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FXR1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- GART | c.2426G>C p.R809T | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); called by muse, mutect2
- GPATCH8 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- GPR182 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 168/281 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR21 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- GRIA4 | c.1715A>T p.E572V | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRK5 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM5 | c.701T>A p.M234K | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GRM8 | c.914G>T p.W305L | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- GUCY1A1 | c.921G>T p.R307S | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- HCK | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEPHL1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 40/286 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- HIF3A | c.1093C>A p.Q365K (on ENST00000377670 / NM_152795.4; = p.Q296K on NM_022462.4) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HIVEP1 | c.5528G>T p.C1843F | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- HIVEP2 | c.4865C>T p.S1622L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- HK3 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HNRNPUL2 | c.1483-2A>C p.X495_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | called by muse, varscan2
- HOXA11 | c.660C>G p.S220R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- HPS5 | c.1944A>T p.E648D (on ENST00000349215 / NM_181507.2; = p.E534D on NM_007216.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2
- HRCT1 | c.111G>T p.Q37H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.586); called by muse, varscan2
- IFI16 | c.2092G>T p.V698L (on ENST00000295809 / NM_001364867.2; = p.V642L on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, varscan2
- IGKV2D-30 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- INPP4B | c.2643-1G>A p.X881_splice | Splice Site (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2
- INTS2 | c.1809A>G p.I603M | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- INTS8 | c.1192A>T p.T398S | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ITIH3 | c.2392del p.D798Tfs*42 | Frame Shift Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- ITSN2 | c.4153G>T p.A1385S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JPH3 | c.950G>T p.S317I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- KCNA10 | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNH1 | c.1010C>A p.P337Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KCNH8 | c.2756G>T p.R919M | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNK6 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- KCNN2 | c.1401G>T p.M467I (on ENST00000264773; = p.M679I on NM_021614.4) | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- KCNN2 | c.1402G>T p.E468* (on ENST00000264773; = p.E680* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 24/132 reads (18%) | called by muse, mutect2, varscan2
- KIF1B | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- KRT16 | c.1228C>A p.L410M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT33B | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KRTAP4-3 | c.263G>C p.S88T | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, varscan2
- LAMA2 | c.909+1G>A p.X303_splice | Splice Site (SNP) | VAF 67/230 reads (29%) | called by muse, mutect2, varscan2
- LAMB1 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LGI2 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIPI | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- LRRC7 | c.1881G>T p.K627N (on ENST00000651989 / NM_001370785.2; = p.K594N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- MADD | c.3310A>G p.K1104E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MAGED1 | c.2325C>G p.F775L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- MAML2 | c.1461G>T p.Q487H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MAP2 | c.3934G>C p.A1312P | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MARCHF8 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MET | c.3992C>G p.S1331C | Missense Mutation (SNP) | VAF 19/234 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); called by muse, mutect2
- MGAM2 | c.3448+1del | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- MISP | c.1781-2A>T p.X594_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- MMRN1 | c.1617C>A p.S539R | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- MMUT | c.1092C>A p.Y364* | Nonsense Mutation (SNP) | VAF 40/207 reads (19%) | called by muse, mutect2, varscan2
- MNDA | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- MOG | c.44C>A p.S15Y | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.03); called by mutect2, varscan2
- MOG | c.731-4C>G | Splice Region (SNP) | VAF 25/255 reads (10%) | called by muse, mutect2
- MRPL43 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MTCL1 | c.3225G>T p.R1075S (on ENST00000306329 / NM_001378206.1; = p.R756S on NM_015210.4) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MUC12 | c.5581G>T p.G1861C (on ENST00000379442; = p.G1718C on NM_001164462.1) | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MUC17 | c.11324C>A p.S3775Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MYO18B | c.2939A>T p.Y980F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MYO3B | c.2993T>C p.L998P | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2
- NELL1 | c.2215G>T p.A739S | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- NFIA | c.642G>T p.Q214H | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NOS2 | c.802G>C p.A268P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH3 | c.5692G>A p.D1898N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); called by muse, mutect2
- NPAP1 | c.1747C>A p.P583T | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- NRXN1 | c.1152C>A p.H384Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- NSMF | c.261del p.S88Afs*37 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- NTRK3 | c.1801G>A p.V601I | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OR10K1 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11A1 | c.464T>A p.V155E | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- OR1G1 | c.851T>A p.M284K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR2C1 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR2T33 | c.362A>T p.Y121F | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR2T8 | c.362A>T p.Y121F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by mutect2, varscan2
- OR4X1 | c.596C>A p.T199N | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- OR5D16 | c.458G>T p.W153L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- OR5H1 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- OR5K1 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- OR5T2 | c.924C>A p.D308E | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR6C1 | c.934A>T p.T312S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH7 | c.3178C>A p.R1060S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PCDHA2 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PDXDC1 | c.1040A>T p.Y347F | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); called by muse, mutect2
- PEX5L | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.095); called by muse, mutect2
- PKHD1 | c.10646G>T p.G3549V | Missense Mutation (SNP) | VAF 84/364 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PKHD1L1 | c.11419G>C p.A3807P | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- PLCL1 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- POTEF | c.2242C>A p.H748N | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEJ | c.2413C>A p.L805M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- POU6F2 | c.192G>T p.G64= | Splice Region (SNP) | VAF 33/168 reads (20%) | called by muse, mutect2, varscan2
- PRG4 | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 55/753 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.414); called by muse, mutect2
- PRKG1 | c.1342T>C p.Y448H | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTDSS1 | c.557A>C p.Y186S | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- PTPRZ1 | c.2632G>C p.D878H | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PXDNL | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.216); called by muse, mutect2
- PYHIN1 | c.798G>T p.K266N | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- RBM12B | c.70A>G p.T24A | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2
- RCSD1 | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- REEP3 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- RIPK3 | c.1430G>T p.W477L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF43 | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPO1 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTKN | c.1237C>T p.Q413* (on ENST00000272430 / NM_001015055.2; = p.Q400* on NM_033046.2) | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- SDK1 | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SEMA5A | c.1891G>T p.G631C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SERPINB3 | c.273A>T p.E91D | Missense Mutation (SNP) | VAF 61/371 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- SFTPD | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- SIPA1L2 | c.4492G>T p.G1498W | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SKOR2 | c.2559C>A p.S853R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- SLC22A11 | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SLC47A2 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); called by muse, varscan2
- SLC5A11 | c.791C>A p.P264Q | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC5A8 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A2 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLITRK3 | c.782G>T p.C261F | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SMC1A | c.766A>G p.M256V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAPC4 | c.551-1G>T p.X184_splice | Splice Site (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- SNX7 | c.1057G>C p.D353H | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SPATA31A7 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by mutect2, varscan2
- SPINK14 | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- SPPL3 | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SPTAN1 | c.4168G>T p.A1390S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SRBD1 | c.2659G>T p.D887Y | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- STYXL2 | c.3347G>T p.R1116L | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SZT2 | c.2752G>T p.G918* | Nonsense Mutation (SNP) | VAF 26/124 reads (21%) | called by muse, mutect2, varscan2
- TAF1L | c.4647C>A p.H1549Q | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TAMALIN | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- TAOK1 | c.2060C>A p.T687N | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.206); called by muse, varscan2
- TDO2 | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TECPR1 | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TG | c.7998-7T>C | Splice Region (SNP) | VAF 23/331 reads (7%) | called by muse, mutect2
- TMEM131L | c.2931G>T p.K977N | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNFRSF11A | c.510A>T p.R170S | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TNR | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.796_801del p.G266_R267del | In Frame Del (DEL) | VAF 37/126 reads (29%) | called by mutect2, pindel, varscan2
- TPP2 | c.2175+1G>T p.X725_splice | Splice Site (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- TPP2 | c.2175+2T>C p.X725_splice | Splice Site (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- TRHDE | c.2083C>A p.L695I | Missense Mutation (SNP) | VAF 299/625 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRIM49 | c.970A>T p.T324S | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTC6 | c.2525G>T p.W842L | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- TUBD1 | c.934+1_934+18del p.X312_splice | Splice Site (DEL) | VAF 13/62 reads (21%) | called by mutect2, pindel, varscan2
- UBQLN3 | c.1313G>C p.S438T | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- UNC5D | c.2750C>A p.S917Y | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC80 | c.8297G>A p.S2766N | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.275); called by muse, mutect2
- USH2A | c.13214G>A p.C4405Y | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, varscan2
- USH2A | c.6955C>A p.L2319M | Missense Mutation (SNP) | VAF 103/418 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- USH2A | c.6245A>G p.N2082S | Missense Mutation (SNP) | VAF 61/319 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USH2A | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 11/276 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- VPS13B | c.2441G>T p.S814I | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WASF3 | c.363dup p.A122Cfs*2 | Frame Shift Ins (INS) | VAF 42/197 reads (21%) | called by mutect2, pindel, varscan2
- WDFY4 | c.6932G>T p.S2311I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- WDR5 | c.988T>C p.W330R | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WFDC13 | c.281G>C p.*94Sext*48 | Nonstop Mutation (SNP) | VAF 15/196 reads (8%) | called by muse, mutect2
- ZAP70 | c.1131G>T p.K377N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- ZHX1 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- ZMYM4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.052); called by muse, mutect2
- ZNF235 | c.1825A>T p.S609C | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF43 | c.2105G>A p.G702E | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, mutect2
- ZNF438 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF655 | c.734G>T p.C245F | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF768 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.755); called by muse, mutect2
- ZNF80 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN25 | c.796G>T p.V266F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ABCB1 | c.2718C>A p.T906= | Silent (SNP) | VAF 63/395 reads (16%) | catalogued as COSV55945172; called by muse, mutect2, varscan2
- ADAM19 | c.2247C>G p.P749= | Silent (SNP) | VAF 38/158 reads (24%) | called by muse, mutect2, varscan2
- ADAM21 | c.1216C>T p.L406= | Silent (SNP) | VAF 43/297 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.387G>A p.V129= | Silent (SNP) | VAF 26/89 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.1791C>T p.C597= | Silent (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.2316C>A p.R772= | Silent (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- ADRA1B | c.1398C>A p.G466= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- AGAP9 | c.1932G>T p.T644= | Silent (SNP) | VAF 37/78 reads (47%) | called by muse, varscan2
- AOC1 | c.915C>A p.P305= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- AP2A2 | c.684G>C p.L228= | Silent (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- ARL6IP4 | c.1248A>C p.R416= (on ENST00000315580 / NM_018694.3; = p.R397= on NM_016638.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs773635795; called by muse, mutect2, varscan2
- ASTN2 | c.2235T>A p.P745= (on ENST00000313400 / NM_001365069.1; = p.P694= on NM_014010.5) | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as rs1203650856; called by muse, mutect2, varscan2
- C17orf78 | c.255G>A p.E85= | Silent (SNP) | VAF 9/203 reads (4%) | called by muse, mutect2
- CACNG3 | c.805C>A p.R269= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as COSV50067779; called by muse, mutect2, varscan2
- CARD11 | c.1035G>A p.E345= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as rs771091149; called by muse, mutect2, varscan2
- CCL5 | c.199C>A p.R67= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs761483805; called by muse, mutect2, varscan2
- CDH10 | c.27G>T p.L9= | Silent (SNP) | VAF 32/172 reads (19%) | called by muse, varscan2
- CNTNAP3 | c.1953G>C p.P651= | Silent (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- COL6A5 | c.2673C>A p.T891= | Silent (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- DDIT4L | c.280C>A p.R94= | Silent (SNP) | VAF 32/205 reads (16%) | called by muse, mutect2, varscan2
- DNASE2B | c.648C>A p.A216= | Silent (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- DNMT3B | c.381G>C p.R127= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- DPPA4 | c.462G>T p.G154= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as rs753329314; called by muse, mutect2, varscan2
- DRD3 | c.669C>A p.I223= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- ERLIN1 | c.786T>C p.A262= | Silent (SNP) | VAF 30/236 reads (13%) | catalogued as rs370132690; called by muse, mutect2, varscan2
- FAT4 | c.13338C>T p.G4446= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- FBXO21 | c.1704G>A p.L568= (on ENST00000330622 / NM_033624.3; = p.L561= on NM_015002.3) | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, varscan2
- FOXL1 | c.492C>A p.R164= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- GABRA4 | c.1476C>A p.T492= | Silent (SNP) | VAF 52/303 reads (17%) | catalogued as COSV99974503; called by muse, mutect2, varscan2
- GART | c.1713A>T p.T571= | Silent (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- GAS2L2 | c.2202C>A p.A734= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- GMPPA | c.585G>A p.R195= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1171357741; called by muse, mutect2, varscan2
- GRIK1 | c.1437C>T p.C479= | Silent (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- HEPH | c.27C>A p.L9= | Silent (SNP) | VAF 46/111 reads (41%) | called by muse, mutect2, varscan2
- IGDCC4 | c.2097G>C p.V699= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- INTU | c.2304A>G p.P768= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs751174934; called by muse, mutect2, varscan2
- ITIH2 | c.1731C>T p.P577= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs1352799977, COSV64434097; called by muse, mutect2, varscan2
- KBTBD13 | c.255C>A p.A85= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- KCNK9 | c.1047G>A p.S349= | Silent (SNP) | VAF 166/433 reads (38%) | catalogued as rs764816119, COSV57284450; called by muse, mutect2, varscan2
- KIAA1614 | c.342G>A p.K114= | Silent (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- KIF26B | c.4503G>T p.P1501= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2
- KLHL42 | c.1002G>T p.L334= | Silent (SNP) | VAF 139/253 reads (55%) | catalogued as COSV67146101; called by muse, mutect2, varscan2
- KNTC1 | c.2448G>A p.E816= | Silent (SNP) | VAF 9/196 reads (5%) | called by muse, mutect2
- KRT16 | c.471G>T p.R157= | Silent (SNP) | VAF 28/155 reads (18%) | called by muse, mutect2, varscan2
- KRT38 | c.525G>T p.L175= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as COSV99878438; called by muse, mutect2, varscan2
- KRT6A | c.1131C>A p.T377= | Silent (SNP) | VAF 68/332 reads (20%) | catalogued as rs374230378, COSV100417090; called by muse, mutect2, varscan2
- LIPG | c.420G>T p.V140= | Silent (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- LOXHD1 | c.2743C>A p.R915= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV56062266; called by muse, mutect2, varscan2
- MAPK8IP3 | c.591G>T p.L197= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- METTL6 | c.345C>A p.A115= | Silent (SNP) | VAF 32/215 reads (15%) | called by muse, mutect2, varscan2
- MOXD1 | c.1740G>T p.V580= | Silent (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- NECAB2 | c.1026G>A p.E342= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs770711928; called by muse, mutect2, varscan2
- NRAP | c.945C>T p.I315= | Silent (SNP) | VAF 38/185 reads (21%) | catalogued as COSV63489476; called by muse, mutect2, varscan2
- NRXN2 | c.1779C>T p.F593= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- OBSCN | c.1419G>C p.T473= | Silent (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- OPRK1 | c.462G>A p.V154= | Silent (SNP) | VAF 46/253 reads (18%) | catalogued as COSV55574033, COSV99653717; called by muse, mutect2, varscan2
- OR11H12 | c.456T>A p.T152= | Silent (SNP) | VAF 98/960 reads (10%) | catalogued as COSV73569217; called by muse, varscan2
- OR2L2 | c.75C>T p.F25= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as rs201120288, COSV63551743; called by muse, mutect2, varscan2
- OR2L3 | c.558G>T p.L186= | Silent (SNP) | VAF 61/292 reads (21%) | catalogued as COSV63454954; called by muse, varscan2
- OR51A4 | c.801G>T p.R267= | Silent (SNP) | VAF 26/508 reads (5%) | called by muse, mutect2
- OR5T3 | c.549C>T p.S183= | Silent (SNP) | VAF 27/160 reads (17%) | called by muse, mutect2, varscan2
- OR6C75 | c.555C>A p.L185= | Silent (SNP) | VAF 55/419 reads (13%) | called by muse, mutect2, varscan2
- OR8H1 | c.504C>T p.C168= | Silent (SNP) | VAF 23/167 reads (14%) | catalogued as rs745373167, COSV57295118; called by muse, mutect2, varscan2
- OTOF | c.349C>A p.R117= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs773214630; called by muse, mutect2, varscan2
- PCDH11X | c.207C>A p.T69= | Silent (SNP) | VAF 98/222 reads (44%) | catalogued as COSV53445853, COSV53493669; called by muse, mutect2, varscan2
- PDE4B | c.1026G>T p.L342= | Silent (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- PKD1L1 | c.1983C>A p.S661= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV56969201; called by muse, mutect2, varscan2
- PLXNB1 | c.1983C>T p.T661= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs775782990; called by muse, mutect2, varscan2
- PRAMEF27 | c.1251C>T p.A417= | Silent (SNP) | VAF 41/185 reads (22%) | catalogued as rs1486981356; called by muse, mutect2, varscan2
- PRAMEF8 | c.936C>T p.L312= | Silent (SNP) | VAF 23/417 reads (6%) | called by muse, mutect2
- PSD | c.1182C>T p.P394= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, varscan2
- PSG1 | c.258T>A p.G86= | Silent (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- RBM12 | c.1428A>T p.V476= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as COSV58292556; called by muse, mutect2, varscan2
- RGPD4 | c.5214G>T p.T1738= | Silent (SNP) | VAF 46/301 reads (15%) | catalogued as COSV100736630; called by muse, mutect2, varscan2
- RIMS1 | c.2586G>T p.P862= | Silent (SNP) | VAF 41/194 reads (21%) | called by muse, mutect2, varscan2
- RTL3 | c.564C>A p.P188= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- RYR3 | c.13218C>A p.A4406= (on ENST00000389232; = p.A4407= on NM_001036.6) | Silent (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- SERPINB10 | c.942C>T p.A314= | Silent (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- SLAMF7 | c.708C>T p.L236= | Silent (SNP) | VAF 59/265 reads (22%) | catalogued as rs144271994; called by muse, mutect2, varscan2
- SLC26A4 | c.492C>A p.S164= | Silent (SNP) | VAF 46/218 reads (21%) | called by muse, mutect2, varscan2
- SLC35D3 | c.969G>T p.A323= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs376903042, COSV59377632; called by muse, mutect2, varscan2
- SLC45A4 | c.483G>A p.T161= (on ENST00000517878 / NM_001286646.2; = p.T110= on NM_001080431.2) | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs376006337; called by mutect2, varscan2
- SLC8A3 | c.811C>A p.R271= | Silent (SNP) | VAF 46/279 reads (16%) | catalogued as rs758701735, COSV63526016; called by muse, mutect2, varscan2
- SNTG1 | c.699C>A p.V233= | Silent (SNP) | VAF 94/270 reads (35%) | called by muse, mutect2, varscan2
- STARD13 | c.1107G>T p.V369= (on ENST00000336934 / NM_001243476.3; = p.V251= on NM_052851.3) | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- STC1 | c.456C>T p.P152= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs1338405480; called by muse, mutect2, varscan2
- TECTA | c.4593C>T p.F1531= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV50698799; called by muse, mutect2
- TMPRSS11F | c.1263C>A p.V421= | Silent (SNP) | VAF 19/150 reads (13%) | called by muse, mutect2, varscan2
- TRHDE | c.564G>A p.A188= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99671705; called by muse, mutect2
- TRIM29 | c.1059A>G p.R353= | Silent (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- USH2A | c.13086A>T p.P4362= | Silent (SNP) | VAF 44/182 reads (24%) | called by muse, varscan2
- VIP | c.213C>A p.P71= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100923947; called by muse, mutect2
- VSIG1 | c.486C>G p.L162= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- ZFHX4 | c.6015G>T p.P2005= | Silent (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2
- ZMAT1 | c.693G>A p.Q231= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs1049816808; called by muse, mutect2, varscan2
- ZNF557 | c.219C>T p.A73= (on ENST00000414706 / NM_001044388.2; = p.A80= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- ZNF804B | c.2934T>A p.P978= | Silent (SNP) | VAF 39/144 reads (27%) | called by muse, mutect2, varscan2
- AC005863.1 | n.193G>A | RNA (SNP) | VAF 15/73 reads (21%) | catalogued as rs763323372; called by muse, mutect2, varscan2
- AC108734.4 | n.522G>T | RNA (SNP) | VAF 40/123 reads (33%) | called by muse, varscan2
- AC244517.10 | c.36-10658C>T | Intron (SNP) | VAF 10/218 reads (5%) | catalogued as rs890277993; called by muse, mutect2
- ADAM21P1 | n.1672G>T | RNA (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- AGAP12P | n.1885C>A | RNA (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- AL049777.1 | n.510+4711G>C | Intron (SNP) | VAF 61/274 reads (22%) | called by muse, mutect2, varscan2
- ANO3 | c.591+27G>T | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, varscan2
- BCR | c.1279+17083C>T | Intron (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- BLACE | n.1773G>T | RNA (SNP) | VAF 7/28 reads (25%) | called by mutect2, varscan2
- BTBD7 | c.1162+5174G>T | Intron (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- C10orf71 | c.*138G>T | 3'UTR (SNP) | VAF 14/75 reads (19%) | catalogued as COSV100110387; called by muse, mutect2, varscan2
- C2CD6 | c.1581+2980G>C | Intron (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- CALCA | chr11:14967804 C>A | 3'Flank (SNP) | VAF 31/193 reads (16%) | catalogued as COSV100523849; called by muse, mutect2, varscan2
- CCNQP1 | n.185T>G | RNA (SNP) | VAF 31/141 reads (22%) | catalogued as rs1208936323; called by muse, mutect2, varscan2
- CHCHD2P9 | n.5del | RNA (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- CIBAR1 | c.261+1030C>T | Intron (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2
- COL16A1 | c.2772+76C>A | Intron (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- COL4A1 | c.553-18C>T | Intron (SNP) | VAF 104/329 reads (32%) | called by muse, mutect2, varscan2
- COPS9 | chr2:240126621 G>A | 3'Flank (SNP) | VAF 6/64 reads (9%) | catalogued as rs866829325; called by muse, mutect2
- CTAGE11P | n.207G>A | RNA (SNP) | VAF 101/349 reads (29%) | called by muse, mutect2, varscan2
- CUL1 | c.*5T>C | 3'UTR (SNP) | VAF 16/103 reads (16%) | called by muse, mutect2, varscan2
- DBF4B | c.1189+255A>T | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- DCHS2 | n.8310C>A | RNA (SNP) | VAF 31/103 reads (30%) | called by muse, mutect2, varscan2
- ERBB4 | c.*32C>A | 3'UTR (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- F11 | c.485+31G>T | Intron (SNP) | VAF 32/198 reads (16%) | called by muse, varscan2
- GLRXP3 | n.147A>T | RNA (SNP) | VAF 105/378 reads (28%) | catalogued as rs757432607; called by muse, mutect2, varscan2
- GUK1 | chr1:228140236 G>A | 5'Flank (SNP) | VAF 9/32 reads (28%) | called by muse, varscan2
- HBA2 | c.*43C>A | 3'UTR (SNP) | VAF 12/45 reads (27%) | catalogued as rs1357452894; called by muse, mutect2, varscan2
- HBG1 | c.315+41C>G | Intron (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- KCNAB2 | c.1014+27G>T | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as rs768564080; called by muse, mutect2, varscan2
- KCNJ6 | c.-27-112272C>T | Intron (SNP) | VAF 12/66 reads (18%) | catalogued as rs1335753646; called by muse, mutect2, varscan2
- KIR3DL1 | chr19:54835096 G>T | 3'Flank (SNP) | VAF 27/97 reads (28%) | called by muse, mutect2, varscan2
- KLF6 | chr10:3785224 C>A | 5'Flank (SNP) | VAF 24/190 reads (13%) | catalogued as rs1034131301; called by muse, varscan2
- KRT31 | c.*11A>T | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- LINC01164 | n.710G>T | RNA (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- LNX1 | c.380+15690G>T | Intron (SNP) | VAF 13/272 reads (5%) | called by muse, mutect2
- LORICRIN | c.*18G>C | 3'UTR (SNP) | VAF 36/92 reads (39%) | called by muse, varscan2
- METTL26 | chr16:638280 del G | 5'Flank (DEL) | VAF 5/19 reads (26%) | catalogued as rs968105567; called by mutect2, pindel
- MIIP | c.715+10G>T | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- MKRN9P | n.640C>A | RNA (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- MLPH | c.446-66G>T | Intron (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- OR2M1P | n.296C>T | RNA (SNP) | VAF 19/334 reads (6%) | called by muse, mutect2
- OR2M1P | n.758G>T | RNA (SNP) | VAF 64/300 reads (21%) | called by muse, varscan2
- PCYT1A | c.565+78G>T | Intron (SNP) | VAF 55/176 reads (31%) | called by muse, mutect2, varscan2
- PIAS1 | c.24+3171G>T | Intron (SNP) | VAF 21/86 reads (24%) | catalogued as rs1230154230; called by muse, mutect2, varscan2
- PLEKHG3 | c.352-346G>T | Intron (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- RGMB | c.-88del | 5'UTR (DEL) | VAF 2/23 reads (9%) | called by pindel, varscan2
- RIMS2 | c.177-44434C>A | Intron (SNP) | VAF 43/346 reads (12%) | called by muse, mutect2, varscan2
- SH2D3C | c.516-5309G>T | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- SH3BP2 | c.239+473G>T | Intron (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3012G>T | RNA (SNP) | VAF 22/68 reads (32%) | catalogued as rs1255632129; called by mutect2, varscan2
- SPATA13 | c.-222-25930C>T | Intron (SNP) | VAF 13/26 reads (50%) | catalogued as rs1211227931; called by muse, mutect2, varscan2
- SPINK5 | c.-20C>A | 5'UTR (SNP) | VAF 28/191 reads (15%) | catalogued as COSV99805995; called by muse, mutect2, varscan2
- SPINT2 | c.*30G>T | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- SRGAP3 | c.-72_-49del | 5'UTR (DEL) | VAF 21/178 reads (12%) | called by mutect2, pindel
- SRPK1 | c.75-13936G>T | Intron (SNP) | VAF 34/149 reads (23%) | called by muse, mutect2, varscan2
- SSTR5-AS1 | n.1069C>G | RNA (SNP) | VAF 4/19 reads (21%) | called by mutect2, varscan2
- ST7 | c.1254+7441C>T | Intron (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- STAT6 | c.1513-758C>T | Intron (SNP) | VAF 37/469 reads (8%) | called by muse, mutect2
- STMND1 | c.82-4149C>A | Intron (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+56874G>T | Intron (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- TMCO5A | c.*29C>A | 3'UTR (SNP) | VAF 86/256 reads (34%) | called by muse, mutect2, varscan2
- TRIM24 | c.364+331_364+346del | Intron (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- ZIC4 | c.-16+894G>T | Intron (SNP) | VAF 19/290 reads (7%) | called by muse, mutect2
- ZNF292 | c.1020+3672G>T | Intron (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- ZNF619 | c.-83T>A | 5'UTR (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2
